TARGET case TARGET-40-NAAECZ — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7b144141-2fa4-5cde-b14c-b74a9f699ed2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 20 years; Vital status: Dead; Days to death: 449 days (1.2 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 20.0 years (7,311 days); Year of diagnosis: 2004; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 449 days (1.2 years); Sites of involvement: Lung, NOS.
   Treatment given: Protocol identifier: GBCTTO/99.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Mesna.

Follow-up (1 entry)
- Days to follow up: 449 days (1.2 years); Days to first event: 449 days (1.2 years); First event: Death without Remission; Year of follow up: 2006.

Biospecimens (2 samples)
- Sample TARGET-40-NAAECZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAECZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAECZ-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 90
- % Non Tumor Nuclei: Top from Biopsy: 10
- % Cellular Tumor: Top from Biopsy: 12
- % Normal: Top from Biopsy: 78*
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 10
- % Tumor Nuclei: Bottom from Biopsy: 95
- % Non Tumor Nuclei: Bottom from Biopsy: 5
- % Cellular Tumor: Bottom from Biopsy: 45*
- % Normal: Bottom from Biopsy: 53
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 2
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAECZ-06A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 0
- % Non Tumor Nuclei: Top from Biopsy: 100
- % Cellular Tumor: Top from Biopsy: 0
- % Normal: Top from Biopsy: 100 (lung)
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 0
- % Tumor Nuclei: Bottom from Biopsy: 2
- % Non Tumor Nuclei: Bottom from Biopsy: 98
- % Cellular Tumor: Bottom from Biopsy: 3
- % Normal: Bottom from Biopsy: 97 (lung)
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 0
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAECZ-08A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 2
- % Non Tumor Nuclei: Top from Biopsy: 98
- % Cellular Tumor: Top from Biopsy: 25
- % Normal: Top from Biopsy: 70
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 5
- % Tumor Nuclei: Bottom from Biopsy: 0
- % Non Tumor Nuclei: Bottom from Biopsy: 100
- % Cellular Tumor: Bottom from Biopsy: 10(only matrix)
- % Normal: Bottom from Biopsy: 90
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 0
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 449
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Time to first SMN in days: 0
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Therapy: CDDP+ Doxo+ IFO +Mesna
